Gene-level copy-number profile of tumor specimen TARGET-40-PALKGN-01A from TARGET case TARGET-40-PALKGN, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Short bones of lower limb and associated joints; Age at diagnosis: 16.9 years (6,190 days).
Specimen TARGET-40-PALKGN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.ec8204b3-8fc5-534d-8614-a262fad79c92.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PALKGN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 423 have no estimate.
https://portal.gdc.cancer.gov/files/7a7f5366-0d1a-4155-965b-8a10d47bcbad

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 437; copy number 1: 4,193; copy number 2: 7,583; copy number 3: 10,077; copy number 4: 23,616; copy number 5: 9,464; copy number 6: 2,794; copy number 7: 496; copy number 8: 167; copy number 9: 200; copy number 10: 111; copy number 11: 71; copy number 12: 60; copy number 13: 60; copy number 14: 147; copy number 15: 45; copy number 16: 122; copy number 17: 28; copy number 18: 45; copy number 19: 82; copy number 20: 22; copy number 21: 93; copy number 22: 26; copy number 23: 186; copy number 25: 14; copy number 27: 1; copy number 28: 28; copy number 29: 32.

Homozygous deletions (total copy number 0; autosomes only): 121 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:115,802,363–117,139,389, 1 gene (within-gene range 0–2): LSAMP.
- chr3:116,360,024–116,582,830, 3 genes: LSAMP-AS1, LINC00903, RN7SL582P.
- chr3:117,026,698–117,027,039, 1 gene: PTMAP8.
- chr5:163,416,525–168,264,157, 35 genes (within-gene range 0–1): AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B, AC010291.1, AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1.
- chr7:64,425,623–65,463,438, 47 genes: AC022202.1, YWHAEP1, VN1R40P, ZNF680P1, HNRNPCP7, ZNF680, BNIP3P42, AC016769.3, AC016769.1, AC016769.2, AC016769.4, AC016769.5, AC016769.6, ZNF107, BNIP3P11, MIR6839, AC091799.1, AC073349.3, ZNF138, AC073349.4, AC073349.2, SEPHS1P1, EEF1DP4, AC073349.5, ZNF273, AC073349.1, VN1R42P, MTDHP1, AC073210.3, ZNF117, ERV3-1, RNU6-1229P, CCT6P3, AC073210.2, SNORA22C, SNORA15B-1, AC073210.1, GTF2IP14, INTS4P1, AC104073.2, AC104073.1, AC104073.4, AC104073.3, RSL24D1P3, AC092685.1, ZNF92, AC114501.3.
- chr19:94,062–633,537, 34 genes: OR4G3P, OR4G1P, OR4F17, WBP1LP11, OR4F8P, AC092192.1, SEPTIN14P19, CICP19, AC092299.1, AC010507.1, LINC01002, AC010507.2, RNU6-1076P, AC016588.2, PLPP2, MIER2, AC016588.1, THEG, AC010641.2, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2, MADCAM1, AC005775.1, TPGS1, CDC34, GZMM, AC009005.1, BSG, HCN2, AC005559.1, POLRMT.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,362 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:63,249,920–64,192,685, 29 genes, copy number 9: AC096543.2, RPSAP65, FOXD3-AS1, FOXD3, MIR6068, Y_RNA, AL049636.1, ALG6, ITGB3BP, BX004807.1, EFCAB7, RN7SL488P, RNU7-123P, DLEU2L, AL109925.3, AL109925.6, AL109925.4, AL109925.2, AL109925.5, AL109925.1, PGM1, RN7SL130P, ROR1, AL161742.1, CFL1P3, RNU6-809P, Y_RNA, ROR1-AS1, AL445205.1.
- chr1:74,468,195–74,673,792, 4 genes, copy number 9 (within-gene range 5–9): AC105271.1, LRRC53, ERICH3, ERICH3-AS1.
- chr1:76,699,789–78,540,701, 41 genes, copy number 10 (within-gene range 4–10): TPI1P1, RNU6-161P, LINC02567, ST6GALNAC5, MIR7156, AL035409.2, AL035409.1, PIGK, AC113935.1, AC093433.1, AC093433.2, AK5, AC095030.1, RNU7-8P, AC093575.1, ZZZ3, RNA5SP20, RN7SL370P, USP33, ACTG1P21, MIGA1, RNA5SP21, AC138392.1, NSRP1P1, HSPE1P25, NEXN-AS1, NEXN, FUBP1, DNAJB4, GIPC2, AC103591.3, AC103591.4, AC103591.2, RNU6-1102P, AC103591.1, RNA5SP22, RNFT1P2, MGC27382, PTGFR, AC096531.1, RNA5SP23.
- chr1:78,666,272–83,480,024, 38 genes, copy number 9–18: AC104837.2, AC104837.1, ADGRL4, PSAT1P3, AL353651.2, AL353651.1, LINC02792, ADH5P2, AC099671.1, AC098657.1, AC098657.2, AC098657.3, HMGB1P18, AL606519.1, HNRNPA1P64, AL596276.1, AL596276.2, AL136234.1, LINC01781, MTND2P30, RPL7P10, AL357632.1, AC093154.1, RN7SKP247, ADGRL2, HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8, AC117944.1, AL138799.2, ST13P20, AL157944.1, LINC01362, LINC01361, AC116099.1, LINC01712.
- chr1:84,363,706–86,696,311, 47 genes, copy number 14–20 (within-gene range 5–20): UOX, DNASE2B, AL844170.1, RPF1, GNG5, AL359762.3, SPATA1, CTBS, AL359762.1, AL359762.2, LINC01555, AC114482.1, SSX2IP, AC104169.1, LPAR3, MCOLN2, DNAI3, MCOLN3, MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10, AL078459.1, DDAH1, Y_RNA, AL360219.1, AC092807.3, AC092807.2, CCN1, SNORD81, AC092807.1, ZNHIT6, COL24A1, RNA5SP51, AC104455.1, LINC02795, ODF2L, MIR7856, AC119749.1, CLCA2, CLCA1, CLCA4, CDCA4P2, CLCA4-AS1, CLCA3P.
- chr1:89,524,829–93,847,150, 86 genes, copy number 13–25 (within-gene range 6–25) (broad region; genes not listed).
- chr1:98,210,747–98,272,658, 1 gene, copy number 17: LINC01776.
- chr6:38,207,274–38,207,345, 1 gene, copy number 10: AL033518.1.
- chr6:38,675,925–45,664,349, 192 genes, copy number 9–18 (within-gene range 3–18) (broad region; genes not listed).
- chr6:78,604,467–82,169,391, 53 genes, copy number 9 (within-gene range 1–9): AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3, HMGN3-AS1, AL355796.1, Y_RNA, LCAL1, AL355379.1, AL078601.1, AL078601.2, AL391840.1, DBIP1, LCA5, AL391840.3, AL391840.2, AL451064.1, AL451064.2, SH3BGRL2, LINC01621, AL132875.1, AL132875.3, AL132875.2, ELOVL4, AL133475.1, GAPDHP63, RPL35AP18, TTK, AL591135.2, AL591135.1, AK4P5, BCKDHB, AL359715.3, RPL17P25, AL359715.4, AL359715.1, AL359715.2, RPSAP72, AL596028.1, AL590824.1, TENT5A, AL122017.1, AL359693.1, RNA5SP210, AL078599.2, SNORA70, AL078599.1, LINC01526, LINC02542, AL360157.1.
- chr6:83,852,312–85,290,849, 18 genes, copy number 10: AL139232.1, RIPPLY2, CYB5R4, AL034347.1, LINC02857, MRAP2, CEP162, LINC01611, SMARCE1P2, TBX18, TBX18-AS1, AL590143.1, AL035694.1, AL109941.1, AL139806.1, AL122016.1, AL135903.1, KRT18P64.
- chr6:87,513,938–90,587,072, 55 genes, copy number 9–11 (within-gene range 1–11): RARS2, ORC3, AKIRIN2, AL133211.1, Y_RNA, RN7SL183P, AL590392.1, AL136096.1, SPACA1, CNR1, AL121835.2, AL139042.1, AL121835.1, ACTBP8, AL139090.1, RNGTT, SNORA73, AL079342.3, AL079342.1, AL079342.2, RNU2-61P, AL353135.1, PNRC1, RN7SL336P, SRSF12, AL353135.2, PM20D2, GABRR1, GABRR2, TUBB3P1, UBE2J1, RRAGD, NACAP7, ANKRD6, RN7SL11P, AL159174.1, LYRM2, MDN1, AL096678.1, DNAJC19P6, PIMREGP3, CASP8AP2, Y_RNA, RPL22P14, AL353692.1, GJA10, Y_RNA, BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7.
- chr6:136,317,961–139,877,391, 67 genes, copy number 18–29 (broad region; genes not listed).
- chr6:142,301,854–143,831,185, 24 genes, copy number 10 (within-gene range 2–10): ADGRG6, AL359313.1, AL355337.1, AL023584.1, HIVEP2, AL023584.2, AL355304.1, LINC01277, AL023581.2, AIG1, AL023581.1, AL136116.2, AL136116.1, AL136116.3, AL031320.1, ADAT2, TUBB8P2, RNA5SP221, PEX3, AL031320.2, VDAC1P8, FUCA2, PHACTR2, PHACTR2-AS1.
- chr7:5,121,239–8,004,053, 85 genes, copy number 12–14 (within-gene range 6–14) (broad region; genes not listed).
- chr7:8,433,609–12,571,392, 36 genes, copy number 12–15: NXPH1, AC009500.1, AC004852.2, AC004852.1, AC004852.3, GAPDHP68, AC060834.2, PER3P1, AC060834.1, AC006363.1, AC010991.1, AC004936.1, AC004879.1, U3, MGC4859, HSPA8P8, AC009945.1, AC004415.1, Y_RNA, NDUFA4, AC007029.1, PHF14, RPL23AP52, AC004160.1, NPM1P11, THSD7A, AC004160.2, THRAP3P3, TMEM106B, VWDE, AC013470.3, AC013470.2, SSBL5P, TAS2R2P, AC013470.1, AC005281.1.
- chr7:13,339,201–13,365,049, 1 gene, copy number 13: AC011287.2.
- chr7:21,381,363–23,014,130, 23 genes, copy number 15 (within-gene range 7–15): RNU1-15P, AC005094.1, SP4, MIR1183, DNAH11, CDCA7L, RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, AC005682.2, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A.
- chr7:23,450,658–23,832,513, 15 genes, copy number 16: RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7.
- chr9:60,914,407–63,143,401, 65 genes, copy number 9 (broad region; genes not listed).
- chr16:11,976,734–12,574,287, 1 gene, copy number 9 (within-gene range 2–19): SNX29.
- chr16:12,081,237–14,632,728, 40 genes, copy number 9–19 (within-gene range 3–19): RPS23P6, AC007601.1, AC007601.2, AC092365.1, AC007598.2, AC007598.1, AC007598.3, AC131391.1, AC010333.1, AC010333.2, AC010333.3, CPPED1, MIR4718, AC109597.1, AC109597.2, AC092324.1, RPL35AP34, SHISA9, AC009134.1, U91319.1, AC003009.1, TMF1P1, U95743.1, ERCC4, RPS26P52, AC010401.1, AC010401.2, LINC02185, LINC02186, MRTFB, AC130650.2, AC130650.1, TVP23CP2, Y_RNA, MIR193BHG, MIR193B, MIR365A, LINC02130, AC040173.1, PARN.
- chr17:7,686,071–19,897,287, 439 genes, copy number 10–28 (broad region; genes not listed).
- chr17:19,929,372–19,929,737, 1 gene, copy number 19: AC005730.3.

Autosomal genes at a single copy (total copy number 1): 2,308. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
